Somatic mutation profile of tumor specimen 0DS10A from CCDI case PBCGPB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.8 years (284 days).
Specimen 0DS10A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70cd01d3-4356-4dff-84e0-8ad19cd106ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRPJ9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4a90fb-e1fe-401e-878b-de5e21bc3e53

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, 3'UTR 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM88 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 53/768 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs555248604; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 31/619 reads (5%) | called by muse, mutect2
- HMG20B | c.472+35C>A | Intron (SNP) | VAF 18/186 reads (10%) | catalogued as rs1362730924; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 13/104 reads (13%) | called by muse, varscan2
